MMRF case MMRF_1392 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7089287d-86e9-4e0d-b687-fef149f4e476

Demographics
Sex at birth: male; Race: other; Ethnicity: hispanic or latino; Age at index: 41 years; Vital status: Dead; Days to death: 769 days (2.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 41.7 years (15,247 days); ISS stage: I; Days to last known disease status: 769 days (2.1 years); Days to last follow up: 769 days (2.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 463 days (1.3 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 504 days (1.4 years); Days to treatment end: 505 days (1.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 507 days (1.4 years); Days to treatment end: 507 days (1.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 595 days (1.6 years); Days to treatment end: 764 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 595 days (1.6 years); Days to treatment end: 763 days (2.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 595 days (1.6 years); Days to treatment end: 769 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 769.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 172 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.175 mg/dL; Immunoglobulin G 20.3 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 7.39 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 50 g/L; Total Protein 9.4 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 84 (ECOG 0): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.332 mg/dL; Immunoglobulin G 5.33 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.09 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L.
- Day 168 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.829 mg/dL; Immunoglobulin G 4.57 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 49 g/L; Total Protein 7.2 g/dL; Glucose 5.61 mmol/L.
- Day 252 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.171 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 3.84 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 364 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.5 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 448 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.597 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.968 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 47 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 535 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.94 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 595 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 4.35 mmol/L.
- Day 714 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.244 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.52 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -5: Weight: 105 kg; Height: 191 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1392_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1392_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
